CPTAC case C3N-02283 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d3c4d18f-aab6-401d-a27a-8a92dd9a4660

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 67.3 years (24,583 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Residual disease: R0; Days to last known disease status: 1,902 days (5.2 years); Progression or recurrence: no; Days to last follow up: 1,902 days (5.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.1 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 16; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 108 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 221 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Follow-up contacts recording only the day: day 606, day 934, day 1,522, day 1,902.

Other clinical attributes
- Weight: 98 kg; Height: 181 cm; BMI: 29.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 90; Cigarettes per day: 40; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 2015; Exposure duration years: 45.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02283-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -52 days; Initial weight: 320 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02283-22: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-02283-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -52 days; Method of sample procurement: Blood Draw.
